Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0J6, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0J6-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:
Palpable breast mass, FNA positive malignant cells.

Specimens Submitted:

- 1: SP: Sentinel node #1 level one left axilla (fs)
- 2: SP: Sentinel node #2 level one left axilla (fs)
- 3: SP: Non sentinel lymph node left axilla
- 4: SP: Sentinel node #3, level one left axilla (fs)
- 5: SP: Left breast mass

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1 LEVEL I LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE, (0/1).
- ADDITIONAL H/E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3)
- SHOW NO EVIDENCE OF METASTATIC TUMOR.
- 2) LYMPH NODE, SENTINEL #2 LEVEL 1 LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE, (0/1).
- ADDITIONAL H/E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3)
- SHOW NO EVIDENCE OF METASTATIC TUMOR.
- 3) LYMPH NODE, NON-SENTINEL LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE, (0/1).
- BENIGN FIBROADIPOSE TISSUE AND NERVE.
- 4) LYMPH NODE, SENTINEL #3 LEVEL 1 LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE, (0/1).
- ADDITIONAL H/E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3)
- SHOW NO EVIDENCE OF METASTATIC TUMOR.
- 5) BREAST, LEFT; EXCISION:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, POORLY DIFFERENTIATED, ASSOCIATED WITH PROMINENT INFLAMMATORY INFILTRATE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 4.5 CM IN

** Continued on next page **

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 NW 10/22/11

See is (circle):		

[page 2 of 5]
LARGEST DIMENSION

Page 2 of 5

GROSSLY.

- AN IN SITU COMPONENT IS NOT IDENTIFIED.
- CALCIFICATIONS ARE PRESENT FOCALLY IN BENIGN BREAST PARENCHYMA.
- NO VASCULAR INVASION IS NOTED.
- THE MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA, (SEE NOTE). THE NEAREST (POSTERIOR)

MARGIN HAS A CLEARANCE OF 0.7CM MICROSCOPICALLY.

- THE SKIN IS NOT INVOLVED BY CARCINOMA.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS FIBROADENOMATOID AND BIOPSY

SITE CHANGES.

- IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED ON FORMALIN-FIXED TISSUE WITH THE FOLLOWING

RESULTS FOR INVASIVE CARCINOMA (BLOCK 5 T 8):

ESTROGEN RECEPTOR (6F11,

0 % NUCLEAR STAINING

PROGESTERONE RECEPTOR (1E2; ,

0 % NUCLEAR STAINING

HER2 (HERCEPTEST;

NEGATIVE (0)

(0% OF INVASIVE TUMOR CELLS EXHIBIT COMPLETE MEMBRANOUS STAINING;
UNIFORMITY OF STAINING: ABSENT;
HOMOGENEOUS, DARK CIRCUMFERENTIAL PATTERN: ABSENT)

CONTROLS ARE SATISFACTORY.

COMMENT: HERCEPTESTM IS AN FDA-APPROVED METHOD FOR ASSESSMENT OF
HER2 PROTEIN OVEREXPRESSION IN BREAST CANCER TISSUE ROUTINELY PROCESSED FOR
HISTOLOGICAL EVALUATION. THE HER2 TEST RESULTS ARE REPORTED IN ACCORDANCE
WITH THE ASCO/CAP GUIDELINE RECOMMENDATIONS FOR HER2 TESTING IN BREAST
CANCER (J CLIN ONCOL 2007; 25(1):118-145).

NOTE: SLIDE 5-L-12 REVIEWED AT DAILY INTRADEPARTMENTAL CASE REVIEW
CONFERENCE

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out *** 1

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

MD

1). The specimen is received fresh for frozen section consultation, labeled

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
"Sentinel node number 1, level 1, left axilla" and consists of a single pink tan fatty lymph node measuring 1.8 cm in greatest dimension. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "Sentinel node #2, level one, left axilla" and consists of a single pink tan fatty lymph node measuring 1.6 cm in greatest dimension. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

3). The specimen is received in formalin, labeled "non-sentinel lymph nodes, left axilla" and consists of fibroadipose tissue and potential lymph nodes ranging from 0.4 to 2.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN potential lymph nodes
BLN-- bisected lymph nodes

4). The specimen is received fresh for frozen section consultation, labeled "Sentinel node #3, level one, left axilla" and consists of a single pink tan fatty lymph node measuring 1.1 cm in greatest dimension. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

5.) The specimen is received fresh, labeled "Left breast mass, short stitch -- superior, long -- lateral" and consists of a 14 x 9 x 4.9 cm, piece of fibrofatty breast tissue with an overlying of 12.5 x 1.3 x 0.2 cm wrinkled tan-pink skin ellipse. A short stitch indicates the superior margin, and a long stitch indicates the lateral margin of excision. The specimen is inked superior -- blue, inferior green, anterior -- red, posterior -- black, medial -- orange, and lateral -- yellow. Serial sectioning reveals a 4.5 x 3.0 x 3.0 cm well-circumscribed, firm, focally hemorrhagic, tan-white stellate mass located 0.7 cm from the posterior closest margin of excision. Sectioning through the remaining breast tissue reveals an abundant amount of dense white fibrous tissue with a moderate amount of yellow, lobulated adipose. The inferior, medial and lateral margins are shaved and entirely submitted separately. Perpendicular sections of the superior, anterior and posterior margins are submitted. Representative sections of the tumor and

** Continued on next page **

[page 4 of 5]
the remaining tissue are submitted.

Page 4 of 5

Summary of sections:

SP - superior margin (perpendicular)
I - inferior margin
M - medial margin
L - lateral margin
AP - anterior margin (perpendicular)
PP - posterior margin (perpendicular)
T - tumor
SS - serial sections remaining tissue

Summary of Sections:

Part 1: SP: Sentinel node #1 level one left axilla(fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Sentinel node #2 level one left axilla (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: SP: Non sentinel lymph node left axilla

Block	Sect. Site	PCs
2	bln	2
1	ln	1

Part 4: SP: Sentinel node #3, level one left axilla (fs)

Block	Sect. Site	PCs
1	{not entered}	1

Part 5: SP: Left breast mass

Block	Sect. Site	PCs
1	AP	1
3	I	5
1	L	1
1	M	1
1	PP	1
1	SP	1
2	SS	2
3	T	3

** Continued on next page **

[page 5 of 5]
----- Page 5 of 5
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #1 LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

2) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #2 LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

4) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #3, LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

, MD

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #1 LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

2) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #2 LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

4) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #3, LEVEL ONE
LEFT AXILLA (FS) BENIGN
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file f59b4ccd-126f-49d5-a082-e8aa980769ff (TCGA-AO-A0J6.CE2FF4D3-B82C-4435-AE1C-3E2E6F104271.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).